Somatic mutation profile of tumor specimen TCGA-DH-A7US-01A (aliquot TCGA-DH-A7US-01A-11D-A33T-08) from TCGA case TCGA-DH-A7US, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.5 years (18,429 days).
Specimen TCGA-DH-A7US-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0ab704d-e1fe-4d1c-81c3-0f986795204b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A7US-10A (Blood Derived Normal), aliquot TCGA-DH-A7US-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77b59a29-67a2-4dcb-b93e-b0ac89f82f79

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 11/115 reads (10%) | hotspot (GDC flag); catalogued as COSV50546815, COSV50546856, COSV50551122; called by muse, mutect2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 82/231 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARSI | c.1050G>A p.W350* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV100156004, COSV60817242; called by muse, mutect2, varscan2
- ASMT | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200351811, COSV101172475; called by muse, mutect2
- ATP7B | c.3353G>A p.R1118H | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs202233544, CD054307, COSV99666330, COSV99666506; called by muse, mutect2, varscan2
- BOD1L1 | c.3983A>G p.Q1328R | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV99239502; called by muse, mutect2, varscan2
- CLCA4 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as rs1341297561, COSV55365860; called by muse, mutect2, varscan2
- EIF4A1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs865904208, COSV51510726; called by muse, mutect2, varscan2
- ELP4 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 91/339 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV100635565; called by muse, mutect2, varscan2
- GRK4 | c.710G>T p.R237I (on ENST00000398052 / NM_182982.3; = p.R205I on NM_005307.3) | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs199873516, COSV61669412; called by muse, mutect2
- IGDCC4 | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.587); catalogued as COSV100732829, COSV100732931; called by muse, mutect2, varscan2
- LRP1B | c.8450G>A p.C2817Y | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257729; called by muse, mutect2
- LTBP1 | c.3200G>A p.G1067D (on ENST00000404816 / NM_206943.4; = p.G741D on NM_000627.4) | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99698349; called by muse, mutect2, varscan2
- MTMR3 | c.1774C>G p.P592A | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.416); catalogued as COSV100070924; called by muse, mutect2
- OR8D1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as rs564327621, COSV63442033; called by muse, mutect2
- SDS | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs540701675, COSV99981071; called by muse, mutect2, varscan2
- SERPINA3 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1472427003, COSV101261720; called by muse, mutect2, varscan2
- SMARCA4 | c.3530A>G p.D1177G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758607, COSV60805202; called by muse, mutect2, varscan2
- SMC6 | c.3091G>T p.D1031Y | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100705149, COSV61176849; called by muse, mutect2, varscan2
- STAB1 | c.3027+1G>A p.X1009_splice | Splice Site (SNP) | VAF 31/179 reads (17%) | catalogued as COSV100401813; called by muse, mutect2, varscan2
- ZBTB16 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs780881752, COSV60092102; called by muse, mutect2, varscan2
- ZBTB20 | c.1960C>T p.R654C (on ENST00000474710 / NM_001164342.2; = p.R581C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61849776; called by muse, mutect2
- ZBTB20 | c.734C>T p.S245L (on ENST00000474710 / NM_001164342.2; = p.S172L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV61862290, COSV61865417; called by muse, mutect2, varscan2
- ZSWIM3 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99666590; called by muse, mutect2
- ATF7IP | c.3193_3196del p.T1065Lfs*42 | Frame Shift Del (DEL) | VAF 50/201 reads (25%) | called by mutect2, pindel*, varscan2*
- CFL2 | c.17_18del p.T6Sfs*3 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by mutect2, pindel, varscan2
- CDHR2 | c.2985C>T p.A995= | Silent (SNP) | VAF 33/449 reads (7%) | catalogued as rs776432737, COSV99991694; called by muse, mutect2
- DAB2IP | c.1563C>G p.L521= (on ENST00000408936; = p.L493= on NM_032552.3) | Silent (SNP) | VAF 90/219 reads (41%) | catalogued as COSV52267163; called by muse, mutect2, varscan2
- DLGAP4 | c.141C>A p.P47= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV100211330; called by muse, mutect2, varscan2
- HYKK | c.150C>G p.V50= | Silent (SNP) | VAF 73/237 reads (31%) | catalogued as rs775072984, COSV100856461; called by muse, mutect2, varscan2
- OR5H14 | c.123G>A p.G41= | Silent (SNP) | VAF 239/700 reads (34%) | catalogued as COSV71193941, COSV71194116; called by muse, mutect2, varscan2
- PNMA8B | c.192C>T p.A64= | Silent (SNP) | VAF 106/186 reads (57%) | catalogued as COSV100885435; called by muse, mutect2, varscan2
- RASGRF1 | c.2193G>A p.P731= | Silent (SNP) | VAF 65/180 reads (36%) | catalogued as rs766902534, COSV67250171; called by muse, mutect2, varscan2
- SLC26A2 | c.837G>A p.R279= | Silent (SNP) | VAF 50/263 reads (19%) | catalogued as COSV99640195; called by muse, mutect2, varscan2
- ZNF831 | c.3921T>C p.S1307= | Silent (SNP) | VAF 16/455 reads (4%) | catalogued as rs995037651, COSV100926063; called by muse, mutect2
- FAM169B | n.781C>T | RNA (SNP) | VAF 34/88 reads (39%) | catalogued as rs200050409, COSV60568378; called by muse, mutect2, varscan2
